MMRF case MMRF_1274 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/359ffef9-902b-411f-b609-5ab6411f2406

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 41.0 years (14,963 days); ISS stage: I; Days to last known disease status: 1,568 days (4.3 years); Days to last follow up: 1,568 days (4.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 54 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 50 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 92 days; Days to treatment end: 92 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 118 days; Days to treatment end: 118 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 291 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 289 days; Days to treatment end: 292 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 291 days; Days to treatment end: 291 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: First line of therapy; Days to treatment start: 293 days; Days to treatment end: 293 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,568.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -15 (ECOG 1): M Protein 2.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.195 mg/dL; Immunoglobulin G 16.6 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 1.58 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.53 mmol/L; Albumin 40 g/L; Total Protein 8.8 g/dL; Glucose 5.89 mmol/L.
- Day 92 (ECOG 0): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.618 mg/dL; Immunoglobulin G 9.01 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 6.16 mmol/L.
- Day 184 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.715 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.619 mg/dL; Immunoglobulin G 7.66 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.07 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 254 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.738 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.273 mg/dL; Immunoglobulin G 7.71 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.83 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 6.4 g/dL; Glucose 7.81 mmol/L.
- Day 349: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 3.74 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 7.7 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.55 mmol/L; Albumin 47 g/L; Total Protein 6.8 g/dL; Glucose 6.05 mmol/L.
- Day 419 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.088 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.163 mg/dL; Immunoglobulin G 3.01 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 6.9 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.
- Day 511 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.122 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.504 mg/dL; Immunoglobulin G 5.06 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 6.43 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.56 mmol/L.
- Day 603 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.418 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.532 mg/dL; Immunoglobulin G 6.92 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.47 µg/mL; Lactate Dehydrogenase 7.38 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 7.04 mmol/L.
- Day 698 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.887 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.928 mg/dL; Immunoglobulin G 7.37 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.44 µg/mL; Lactate Dehydrogenase 7.15 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.61 mmol/L.
- Day 814 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 9.94 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.23 mmol/L.
- Day 904 (ECOG 1): Lactate Dehydrogenase 7.32 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.62 mmol/L.
- Day 988 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.07 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.98 g/L; Lactate Dehydrogenase 7.82 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 5.28 mmol/L.
- Day 1,056 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.96 g/L; Lactate Dehydrogenase 8.4 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 5.61 mmol/L.
- Day 1,134 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.19 mg/dL; Immunoglobulin G 25.7 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 1.68 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 8 g/dL; Glucose 5.28 mmol/L.
- Day 1,219 (ECOG 1): Lactate Dehydrogenase 9.8 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 307 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.9 g/dL; Glucose 5.89 mmol/L.
- Day 1,287 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.69 mg/dL; Immunoglobulin G 21.6 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 2.75 g/L; Beta 2 Microglobulin 2.78 µg/mL; Lactate Dehydrogenase 8.4 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 7.7 g/dL; Glucose 5.45 mmol/L.
- Day 1,374 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.93 mg/dL; Immunoglobulin G 23.9 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 2.94 g/L; Beta 2 Microglobulin 3.42 µg/mL; Lactate Dehydrogenase 7.78 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 6.71 mmol/L.
- Day 1,465 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.27 mg/dL; Immunoglobulin G 24.8 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 2.76 g/L; Beta 2 Microglobulin 3.48 µg/mL; Lactate Dehydrogenase 7.33 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 8.2 g/dL; Glucose 5.5 mmol/L.
- Day 1,556 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 1.73 g/L; Beta 2 Microglobulin 1.85 µg/mL; Lactate Dehydrogenase 5.93 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 10.1 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day -15: Weight: 110 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1274_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -15 days.
- Sample MMRF_1274_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -15 days.
